Somatic mutation profile of tumor specimen TARGET-20-PANINI-09A (aliquot TARGET-20-PANINI-09A-03D) from TARGET case TARGET-20-PANINI, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 16.8 years (6,118 days).
Specimen TARGET-20-PANINI-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fe7f3aa5-a917-4e6e-a746-503c4da8b86c.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANINI-14A (Bone Marrow Normal), aliquot TARGET-20-PANINI-14A-02D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c1fce911-c8f2-472a-a3ee-0d8a86796bac

The open-access MAF lists 8 somatic variants for this specimen: 8 protein-altering or splice-affecting.
By variant classification: Missense Mutation 5, Frame Shift Del 1, Frame Shift Ins 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EP300 | c.3491G>A p.C1164Y | Missense Mutation (SNP) | VAF 37/135 reads (27%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54335593, COSV54335605; called by muse, mutect2, varscan2
- NF1 | c.2033dup p.I679Dfs*21 | Frame Shift Ins (INS) | VAF 27/118 reads (23%) | catalogued as rs587781807; ClinVar: pathogenic; called by mutect2, varscan2
- CEBPA | c.934_936dup p.Q312dup | In Frame Ins (INS) | VAF 40/95 reads (42%) | catalogued as COSV57198430; called by mutect2, varscan2
- DHX15 | c.491C>T p.S164F | Missense Mutation (SNP) | VAF 37/160 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61028395; called by muse, mutect2, varscan2
- GATA2 | c.962T>C p.L321P | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62003239, COSV62003719, COSV62003772; called by muse, mutect2
- MYC | c.176C>T p.P59L (on ENST00000377970; = p.P74L on NM_002467.6) | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1294281543, COSV52368162, COSV52368882, COSV52375206; called by muse, mutect2
- MYC | c.178C>A p.P60T (on ENST00000377970; = p.P75T on NM_002467.6) | Missense Mutation (SNP) | VAF 7/144 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52367103, COSV52375216, COSV52378928; called by muse, mutect2
- TET2 | c.2090del p.P697Qfs*3 | Frame Shift Del (DEL) | VAF 29/267 reads (11%) | catalogued as COSV54419152; called by mutect2, pindel, varscan2
